Somatic mutation profile of tumor specimen TCGA-D1-A16I-01A (aliquot TCGA-D1-A16I-01A-11D-A12J-09) from TCGA case TCGA-D1-A16I, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: High Grade; Age at diagnosis: 62.5 years (22,836 days).
Specimen TCGA-D1-A16I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d6b619f-00e0-44e0-8943-1e1fb3645499.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A16I-10A (Blood Derived Normal), aliquot TCGA-D1-A16I-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa49caf2-b72b-43eb-8948-3576f1549c95

The open-access MAF lists 40 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, Frame Shift Del 3, Splice Site 2, Nonsense Mutation 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1322G>A p.R441Q (on ENST00000281708 / NM_001349798.2; = p.R361Q on NM_018315.5) | Missense Mutation (SNP) | VAF 163/371 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV55898232, COSV55900020, COSV55902900; called by muse, mutect2, varscan2
- TP53 | c.994-1G>C p.X332_splice | Splice Site (SNP) | VAF 51/63 reads (81%) | hotspot (GDC flag); catalogued as rs587782272, CS002470, CS033842, CS103209, COSV52668116, COSV52746625, COSV52766192; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- AKAP13 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV63452078; called by muse, mutect2
- ATP11A | c.1396-1G>A p.X466_splice | Splice Site (SNP) | VAF 73/196 reads (37%) | catalogued as COSV52108306; called by muse, mutect2, varscan2
- CA12 | c.694C>A p.P232T | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs1294971117, COSV51604715; called by muse, mutect2, varscan2
- CCDC171 | c.3583G>A p.E1195K | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV52636224; called by muse, mutect2, varscan2
- CEP128 | c.2999C>G p.S1000C | Missense Mutation (SNP) | VAF 71/516 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.723); catalogued as COSV55371587; called by muse, mutect2, varscan2
- CFHR2 | c.589T>A p.W197R | Missense Mutation (SNP) | VAF 16/462 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV66380760; called by muse, mutect2
- CHIA | c.1080G>A p.W360* (on ENST00000343320; = p.W252* on NM_021797.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/230 reads (3%) | catalogued as rs1376647802, COSV58474399; called by muse, mutect2
- CHL1 | c.2387A>G p.D796G (on ENST00000397491 / NM_001253387.1; = p.D812G on NM_006614.4) | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV56589315; called by muse, mutect2, varscan2
- DISP1 | c.502A>G p.N168D | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV52656655; called by muse, mutect2, varscan2
- DOCK3 | c.3202G>A p.D1068N | Missense Mutation (SNP) | VAF 271/846 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56510684; called by muse, mutect2, varscan2
- EMILIN2 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs115304890; called by muse, mutect2, varscan2
- ENDOU | c.861C>G p.F287L (on ENST00000422538 / NM_001172439.2; = p.F246L on NM_006025.4) | Missense Mutation (SNP) | VAF 122/346 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV57464763, COSV57465535; called by muse, mutect2, varscan2
- EPS8 | c.2447T>C p.F816S | Missense Mutation (SNP) | VAF 149/332 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.313); catalogued as COSV55528830; called by muse, mutect2, varscan2
- ITPKB | c.1495G>A p.V499M | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV55258835; called by muse, mutect2, varscan2
- MAN1A1 | c.652A>C p.N218H | Missense Mutation (SNP) | VAF 91/398 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63781634; called by muse, mutect2, varscan2
- NLRP8 | c.2404C>A p.P802T | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.053); catalogued as COSV52585006, COSV52591140; called by muse, mutect2, varscan2
- PLEKHO2 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs560563034, COSV60261685; called by muse, mutect2, varscan2
- SRPX | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV59437653; called by muse, mutect2, varscan2
- TENM1 | c.6394C>T p.R2132C | Missense Mutation (SNP) | VAF 91/364 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769678876, COSV64427813; called by muse, mutect2, varscan2
- TNN | c.3734G>C p.R1245T | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV53423484; called by muse, mutect2
- TSPEAR | c.1289T>C p.F430S | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59955986; called by muse, mutect2, varscan2
- VGLL3 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as rs373257893; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1278G>C p.L426F | Missense Mutation (SNP) | VAF 123/284 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60156082; called by muse, mutect2, varscan2
- ZNF334 | c.1027C>A p.H343N | Missense Mutation (SNP) | VAF 62/419 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV61618204; called by muse, mutect2, varscan2
- FBXW7 | c.802_803del p.M268Dfs*18 (on ENST00000281708 / NM_001349798.2; = p.M188Dfs*18 on NM_018315.5) | Frame Shift Del (DEL) | VAF 144/514 reads (28%) | called by pindel, varscan2
- FGFR2 | c.2438_2442del p.P813Hfs*6 | Frame Shift Del (DEL) | VAF 87/358 reads (24%) | called by mutect2, pindel, varscan2
- LCT | c.5009_5011del p.R1670del | In Frame Del (DEL) | VAF 118/394 reads (30%) | called by pindel, varscan2
- ZFHX3 | c.5502_5526del p.L1835Sfs*18 | Frame Shift Del (DEL) | VAF 38/71 reads (54%) | called by mutect2, pindel, varscan2
- BCORL1 | c.33G>A p.V11= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as COSV54392377; called by muse, mutect2, varscan2
- CLDN17 | c.45C>T p.F15= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV54522539; called by muse, mutect2, varscan2
- DCAF16 | c.546G>A p.L182= | Silent (SNP) | VAF 219/509 reads (43%) | catalogued as rs142595985; called by muse, mutect2, varscan2
- GPR75 | c.549C>T p.T183= | Silent (SNP) | VAF 99/184 reads (54%) | catalogued as rs1450369486, COSV61825834; called by muse, mutect2, varscan2
- HDDC2 | c.501C>T p.F167= | Silent (SNP) | VAF 22/256 reads (9%) | catalogued as COSV59532017; called by muse, mutect2
- OBSCN | c.1989C>T p.R663= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs1287296363, COSV52755059; called by muse, mutect2, varscan2
- SCYL2 | c.1233T>C p.P411= | Silent (SNP) | VAF 149/335 reads (44%) | catalogued as COSV62568050; called by muse, mutect2, varscan2
- STK39 | c.1179C>T p.S393= | Silent (SNP) | VAF 124/263 reads (47%) | catalogued as rs746090284, COSV63595575; called by muse, mutect2, varscan2
- ZNF594 | c.2385G>A p.G795= | Silent (SNP) | VAF 212/251 reads (84%) | catalogued as rs761437259, COSV68384921; called by muse, mutect2, varscan2
- AP001425.1 | chr21:38208422 T>C | 5'Flank (SNP) | VAF 30/205 reads (15%) | catalogued as rs1365830174; called by muse, mutect2, varscan2
